Gene-level copy-number profile of tumor specimen TCGA-DK-A1A5-01A from TCGA case TCGA-DK-A1A5, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 79.7 years (29,111 days).
Specimen TCGA-DK-A1A5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.621f23f6-587f-4b2e-8dce-e4a9a3b01434.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DK-A1A5-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6096fa3a-5f50-4637-a887-345e8cd9f8e1

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 14; copy number 1: 617; copy number 2: 19,336; copy number 3: 23,270; copy number 4: 14,645; copy number 5: 547; copy number 6: 522; copy number 7: 47; copy number 8: 578; copy number 9: 58; copy number 10: 74; copy number 11: 32; copy number 15: 3; copy number 16: 7; copy number 25: 2; copy number 26: 28; copy number 33: 13; copy number 38: 13; copy number 39: 2; copy number 46: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DK-A1A5-01A-11D-A13V-01): tumor purity 0.59, ploidy 3.01, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–22,128,103, 14 genes: MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 863 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:32,357,028–32,618,899, 1 gene, copy number 7 (within-gene range 6–7): BIRC6.
- chr2:32,521,927–35,725,142, 39 genes, copy number 7: AL133243.2, AL133243.3, MIR558, AL133243.1, BIRC6-AS2, AL133243.4, TTC27, MIR4765, LINC00486, LINC00486, Y_RNA, LTBP1, H2ACP2, AC019127.1, RNA5SP91, RNA5SP92, MIR4430, RASGRP3, RASGRP3-AS1, FAM98A, AC017050.1, ATP6V0E1P3, HNRNPA1P61, LINC01320, MYADML, SLC25A5P2, LINC01318, AC008170.1, AC073218.1, AC012593.2, AC012593.1, RN7SL602P, AC019064.1, SMIM7P1, AC013442.1, MIR548AD, RNU6-1117P, AC083939.1, MRPL50P1.
- chr7:52,165,235–57,837,046, 175 genes, copy number 8–15 (broad region; genes not listed).
- chr7:81,175,508–81,199,115, 2 genes, copy number 25: AC005008.2, AC005008.1.
- chr11:69,294,151–70,436,584, 36 genes, copy number 7–26: MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.
- chr11:70,477,277–70,477,592, 1 gene, copy number 26: AP001271.1.
- chr16:32,951,993–34,142,849, 58 genes, copy number 9: AC142086.5, IGHV3OR16-10, AC142086.4, IGHV1OR16-4, IGHV3OR16-8, AC145350.2, AC145350.3, HERC2P8, AC145350.4, AC145350.1, ABHD17AP9, AC138869.1, AC138869.2, TP53TG3C, AC138869.3, AC141257.2, TP53TG3E, AC141257.3, TP53TG3B, AC141257.1, AC141257.4, TP53TG3F, AC136944.6, AC136944.5, AC136944.1, AC136944.2, AC136944.4, AC136944.3, AC142384.1, BMS1P8, AC136428.4, ENPP7P13, AC136428.2, IGHV3OR16-12, AC136428.3, IGHV3OR16-13, AC136428.1, AC140658.6, AC140658.7, AC140658.2, IGHV3OR16-11, AC140658.3, ARHGAP23P1, IGHV3OR16-7, AC140658.4, IGHV3OR16-16, AC140658.1, AC140658.5, AC133561.1, BCAP31P1, AC133561.2, AC133561.4, AC133561.3, AC136932.1, DUX4L45, PCMTD1P2, DUX4L46, DUX4L47.
- chr16:59,166,951–73,941,781, 356 genes, copy number 8 (broad region; genes not listed).
- chr16:74,053,365–74,053,965, 1 gene, copy number 8: AC138627.2.
- chr16:74,712,955–78,066,761, 78 genes, copy number 8 (within-gene range 2–8) (broad region; genes not listed).
- chr16:78,123,243–78,275,607, 4 genes, copy number 7–8: AC079414.3, AC009044.1, WWOX-AS1, AC106743.1.
- chr17:39,626,740–40,689,360, 57 genes, copy number 8–33: PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1, ZPBP2, GSDMB, ORMDL3, AC090844.2, LRRC3C, GSDMA, PSMD3, AC090844.3, CSF3, MED24, MIR6884, SNORD124, THRA, NR1D1, AC068669.1, MSL1, CASC3, MIR6866, RAPGEFL1, MIR6867, WIPF2, CDC6, RARA, AC080112.4, RARA-AS1, AC080112.3, GJD3, AC080112.1, PPIAP54, RNA5SP441, AC080112.2, TOP2A, Y_RNA, RPL23AP75, IGFBP4, AC018629.1, TNS4, AC004585.1, CCR7, AC004585.2, SMARCE1, AC073508.2, AC073508.3, KRT222, AC073508.1.
- chr17:56,573,040–56,961,050, 14 genes, copy number 38–39: RPL39P33, NOG, C17orf67, AC106858.1, DGKE, TRIM25, RNU6-1158P, AC015912.2, AC015912.1, MIR3614, AC015912.3, COIL, AC004584.1, AC004584.2.
- chr17:56,982,749–56,985,104, 1 gene, copy number 38: AC004584.3.
- chr17:60,149,942–60,435,996, 8 genes, copy number 7–46: CA4, USP32, SCARNA20, AC104763.1, AC104763.2, H3P42, C17orf64, RPL12P38.
- chr19:38,797,002–39,298,673, 32 genes, copy number 11: RNU6-140P, LGALS4, ECH1, AC008982.1, AC104534.1, HNRNPL, AC008982.2, RINL, AC011455.1, SIRT2, NFKBIB, CCER2, SARS2, AC011455.2, MRPS12, ERVK9-11, FBXO17, AC011455.8, FBXO27, AC010605.1, ACP7, PAK4, AC011443.1, NCCRP1, SYCN, IFNL3P1, IFNL3, IFNL4, MSRB1P1, IFNL4P1, IFNL2, IFNL1.

Autosomal genes at a single copy (total copy number 1): 617. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
